Somatic mutation profile of tumor specimen TCGA-FB-A7DR-01A (aliquot TCGA-FB-A7DR-01A-21D-A33T-08) from TCGA case TCGA-FB-A7DR, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 48.3 years (17,649 days).
Specimen TCGA-FB-A7DR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aaeee9d-d07c-42c3-9168-9c607ec682c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-A7DR-10A (Blood Derived Normal), aliquot TCGA-FB-A7DR-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b19d80-fb70-481a-9bee-93ba2ddf72a8

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/167 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACTN3 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV101557818; called by muse, mutect2
- ADGRA2 | c.1212C>A p.D404E | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV100177690; called by muse, mutect2, varscan2
- ANKMY1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757252599, COSV99801658; called by muse, mutect2
- CATSPER4 | c.459+1G>A p.X153_splice | Splice Site (SNP) | VAF 48/450 reads (11%) | catalogued as COSV58793558; called by muse, varscan2
- CCDC88B | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1275621094, COSV57268061; called by muse, mutect2
- CD59 | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100681163; called by muse, mutect2, varscan2
- CLK3 | c.1846C>A p.L616M (on ENST00000395066 / NM_001130028.1; = p.L468M on NM_003992.4) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as COSV100165844; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2879C>A p.A960D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV99267378; called by muse, mutect2
- DGAT2 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 42/560 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99929609; called by muse, mutect2
- DNAH11 | c.6935C>A p.S2312Y | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178207; called by muse, mutect2, varscan2
- DNAJB11 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99408562; called by muse, mutect2
- GRIA1 | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 62/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs956164570, COSV99598836; called by muse, mutect2, varscan2
- IGBP1P2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 62/528 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as rs1353222687; called by muse, mutect2, varscan2
- KIAA0232 | c.3497G>T p.G1166V | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100300545; called by muse, mutect2, varscan2
- KLHL26 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); catalogued as rs1385020062, COSV56319817; called by muse, mutect2, varscan2
- LRP1B | c.5422G>A p.G1808R | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372934784; called by muse, mutect2, varscan2
- MKX | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748997066, COSV65393548; called by muse, mutect2
- NAB2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55667709; called by muse, varscan2
- NAB2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs542979510, COSV100272605; called by muse, varscan2
- NTN5 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs376960270, COSV99539319; called by muse, mutect2, varscan2
- OR14A16 | c.813T>G p.I271M | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100713725; called by muse, mutect2, varscan2
- PDC | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 51/588 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414783; called by muse, mutect2
- PIWIL3 | c.937del p.E313Kfs*2 | Frame Shift Del (DEL) | VAF 61/487 reads (13%) | catalogued as COSV59994585; called by mutect2, pindel, varscan2
- RTKN2 | c.1565C>A p.T522K | Missense Mutation (SNP) | VAF 102/1011 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100189278; called by muse, mutect2, varscan2
- SLC16A3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 91/701 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs375731251; called by muse, mutect2, varscan2
- SLC17A6 | c.585C>A p.Y195* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV99581069; called by muse, mutect2
- STRAP | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 28/268 reads (10%) | catalogued as COSV99214719; called by muse, mutect2
- TYSND1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV99751827; called by muse, mutect2
- ZIC1 | c.828T>G p.C276W | Missense Mutation (SNP) | VAF 60/677 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291689; called by muse, mutect2
- ZNF341 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV100677790; called by muse, mutect2, varscan2
- KRT76 | c.404del p.G135Vfs*24 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.1651dup p.T551Nfs*9 | Frame Shift Ins (INS) | VAF 47/375 reads (13%) | called by mutect2, varscan2
- ARHGEF17 | c.2889C>T p.P963= | Silent (SNP) | VAF 62/575 reads (11%) | catalogued as rs753577516, COSV99735098; called by muse, mutect2
- DCAF4 | c.297G>A p.K99= | Silent (SNP) | VAF 53/487 reads (11%) | catalogued as COSV100610964, COSV62319673; called by muse, mutect2, varscan2
- IGHM | c.429G>A p.Q143= | Silent (SNP) | VAF 41/264 reads (16%) | called by muse, mutect2, varscan2
- KCNH6 | c.357C>T p.D119= | Silent (SNP) | VAF 33/440 reads (8%) | catalogued as rs770846582, COSV59003000; called by muse, mutect2
- NTRK1 | c.1473C>T p.I491= | Silent (SNP) | VAF 46/450 reads (10%) | catalogued as rs373181158; ClinVar: likely benign; called by muse, mutect2
- TMED1 | c.342C>A p.I114= | Silent (SNP) | VAF 58/574 reads (10%) | catalogued as COSV99284066; called by muse, mutect2, varscan2
- TMEM252 | c.126G>A p.A42= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs147451213; called by muse, mutect2, varscan2
- CEP295 | chr11:93731008 A>C | 3'Flank (SNP) | VAF 75/642 reads (12%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-263C>T | Intron (SNP) | VAF 80/527 reads (15%) | catalogued as rs773131746, COSV54774193; called by muse, mutect2, varscan2
